Somatic mutation profile of cancer-model specimen HCM-BROD-0578-C15-85A (3D Organoid, passage 12; aliquot HCM-BROD-0578-C15-85A-01D-A83U-36), derived from the primary tumor of HCMI case HCM-BROD-0578-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 46.7 years (17,054 days).
Specimen HCM-BROD-0578-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 117dc425-477e-477d-9b68-0056f26d39ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0578-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0578-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38fa7aa0-7891-485b-adc5-50e7cc71396e

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Intron 4, Nonsense Mutation 3, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.9670G>T p.D3224Y | Missense Mutation (SNP) | VAF 185/365 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52506062; called by muse, mutect2, varscan2
- BCORL1 | c.1825C>T p.R609* | Nonsense Mutation (SNP) | VAF 428/430 reads (100%) | catalogued as COSV54392560; called by muse, varscan2
- BID | c.151G>T p.V51F (on ENST00000317361 / NM_197966.2; = p.V5F on NM_001196.4) | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1350104974; called by muse, mutect2, varscan2
- CDH1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 480/480 reads (100%) | catalogued as COSV55727283; called by muse, mutect2, varscan2
- DHX35 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376209770; called by muse, mutect2, varscan2
- FBXO42 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 319/320 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs565632708; called by muse, mutect2, varscan2
- FSTL5 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 147/317 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756146269, COSV60182341; called by muse, mutect2, varscan2
- HCRTR1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 155/303 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.847); catalogued as rs200636229; called by muse, mutect2, varscan2
- HDAC9 | c.2404G>A p.A802T | Missense Mutation (SNP) | VAF 140/333 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1328935755, COSV101287580; called by muse, mutect2, varscan2
- KIF1A | c.5054G>T p.R1685L (on ENST00000320389 / NM_001379639.1; = p.R1677L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 203/429 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as rs1373988210; called by muse, mutect2, varscan2
- OR6T1 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 284/523 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1371737888; called by muse, mutect2, varscan2
- PCDH9 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 74/469 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119000; called by muse, mutect2, varscan2
- RBMXL3 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 430/431 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs782669896, COSV57759992; called by muse, mutect2, varscan2
- RIMS1 | c.4142C>A p.P1381H | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV53453696, COSV53457688; called by muse, mutect2, varscan2
- THADA | c.5382G>C p.Q1794H | Missense Mutation (SNP) | VAF 366/765 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs756831818; called by muse, mutect2, varscan2
- ADAMTS16 | c.2662+1del | Frame Shift Del (DEL) | VAF 84/429 reads (20%) | called by mutect2, pindel, varscan2
- ASCC3 | c.3476T>C p.I1159T | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C7 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 115/306 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCNB1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 202/443 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A5 | c.2396T>C p.F799S | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CTNNA2 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 174/384 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCHS1 | c.4929C>G p.N1643K | Missense Mutation (SNP) | VAF 15/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GABRG3 | c.308C>A p.T103K | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2
- GRM8 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 164/433 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HPGD | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRP6 | c.2911G>C p.D971H | Missense Mutation (SNP) | VAF 243/497 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LTK | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 173/385 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYO16 | c.3818G>A p.W1273* | Nonsense Mutation (SNP) | VAF 390/1088 reads (36%) | called by muse, mutect2, varscan2
- PLIN2 | c.713_718del p.R238_V239del | In Frame Del (DEL) | VAF 48/221 reads (22%) | called by mutect2, pindel, varscan2
- PRRT4 | c.2401G>A p.V801I | Missense Mutation (SNP) | VAF 455/990 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PUM3 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF38 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 135/378 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- TMPO | c.1142G>T p.R381M | Missense Mutation (SNP) | VAF 23/560 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2
- TTC30A | c.686T>A p.M229K | Missense Mutation (SNP) | VAF 231/510 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTP20 | c.1251G>A p.Q417= | Splice Region (SNP) | VAF 124/259 reads (48%) | called by muse, mutect2, varscan2
- ZNF644 | c.2599G>C p.G867R | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CAMK2A | c.1392C>T p.I464= (on ENST00000348628 / NM_171825.2; = p.I475= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 294/712 reads (41%) | catalogued as rs912865720, COSV62245003; called by muse, mutect2
- CGAS | c.237C>T p.A79= | Silent (SNP) | VAF 485/1043 reads (47%) | called by muse, mutect2, varscan2
- ECEL1 | c.1854C>T p.Y618= | Silent (SNP) | VAF 256/517 reads (50%) | catalogued as rs372170199; called by muse, mutect2, varscan2
- HTRA4 | c.210C>T p.R70= | Silent (SNP) | VAF 523/1051 reads (50%) | called by muse, mutect2, varscan2
- LIPF | c.390T>C p.Y130= | Silent (SNP) | VAF 174/381 reads (46%) | called by muse, varscan2
- NFASC | c.3051G>A p.T1017= | Silent (SNP) | VAF 220/466 reads (47%) | catalogued as rs765463710; called by muse, mutect2, varscan2
- OR6P1 | c.51C>T p.F17= | Silent (SNP) | VAF 145/630 reads (23%) | catalogued as COSV58109490; called by muse, mutect2, varscan2
- PHF2 | c.1269G>A p.P423= | Silent (SNP) | VAF 193/561 reads (34%) | catalogued as COSV63683799; called by muse, mutect2, varscan2
- SLC27A6 | c.1126A>C p.R376= | Silent (SNP) | VAF 162/333 reads (49%) | catalogued as COSV99323351; called by muse, mutect2, varscan2
- CSMD2 | c.1326+5847G>T | Intron (SNP) | VAF 10/282 reads (4%) | called by muse, mutect2
- CSNK2A1 | c.213+1497A>G | Intron (SNP) | VAF 398/621 reads (64%) | catalogued as rs192907725; called by muse, mutect2, varscan2
- MTURN | c.163-260T>G | Intron (SNP) | VAF 250/500 reads (50%) | called by muse, mutect2, varscan2
- PSG9 | c.1243+118C>T | Intron (SNP) | VAF 199/412 reads (48%) | catalogued as COSV99392504; called by muse, mutect2, varscan2
